Somatic mutation profile of tumor specimen TARGET-20-PARUTH-09A (aliquot TARGET-20-PARUTH-09A-03D) from TARGET case TARGET-20-PARUTH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.5 years (3,454 days).
Specimen TARGET-20-PARUTH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c52a9efe-a510-4821-81b5-a548a95e21fb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARUTH-14A (Bone Marrow Normal), aliquot TARGET-20-PARUTH-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/216bd687-2edb-4a9c-8b20-62c48660d85b

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 13/132 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CBFB | c.259_260insGGGACTCCT p.D87delinsGDSY | In Frame Ins (INS) | VAF 44/156 reads (28%) | catalogued as COSV52001569; called by mutect2, pindel, varscan2
- BCORL1 | c.4975C>T p.Q1659* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
